Somatic mutation profile of tumor specimen TCGA-24-1467-01A (aliquot TCGA-24-1467-01A-01D-0472-01) from TCGA case TCGA-24-1467, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 51.1 years (18,652 days).
Specimen TCGA-24-1467-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b483793-ad58-4f00-929a-660a2ea08ab7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1467-10A (Blood Derived Normal), aliquot TCGA-24-1467-10A-01W-0545-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a05dff5c-4755-4510-a139-31d80b875068

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 329/389 reads (85%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CACNA1F | c.1592G>T p.C531F | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100544481; called by muse, mutect2, varscan2
- CNTRL | c.2053C>T p.Q685* | Nonsense Mutation (SNP) | VAF 63/216 reads (29%) | catalogued as COSV99441427; called by muse, mutect2, varscan2
- NTSR1 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.837); catalogued as rs988327520, COSV100980622; called by muse, mutect2, varscan2
- ZNF189 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 190/496 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.934); catalogued as COSV99407109; called by muse, mutect2, varscan2
- NF1 | c.2449del p.M817Cfs*4 | Frame Shift Del (DEL) | VAF 41/70 reads (59%) | called by mutect2, pindel, varscan2
- HIPK2 | c.105G>A p.P35= | Silent (SNP) | VAF 91/204 reads (45%) | catalogued as rs377491533; called by muse, mutect2, varscan2
- MVP | c.1593G>A p.T531= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as rs762896179, COSV100651511; called by muse, mutect2
